Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JK, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JK-01A (Primary Tumor).

ICD-O-3

Carcinoma, squamous cell
keratinizing NOS 8071/3

Site Larynx NOS C32.9

W 9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Larynx

1- Recorrenal node

One lymph node uninvolved by neoplasia (0/1)

2- Neck resection – Left:

Five lymph nodes uninvolved by neoplasia (0/5)

3-Recorrenal node – Left:

Squamous cell carcinoma metastasis in one lymph node compromising focally its structure and presenting capsular involvement with associated desmoplasia (1/1).

4 – Total Laryngectomy

Tumor site: Larynx

Squamous cell carcinoma, grade 2 histological with keratinizing pattern

Tumor size: 5.5 cm

Ulceration: present

Discrete tumor lymphocitary infiltrate

Discrete desmoplasia

Mucosa, cartilage plan and skeletal muscle invasion

Lymphatic invasion: present

Vascular invasion: not detected

Scarce intratumor neural invasion

Thyroid gland uninvolved by neoplasia with lymphocytic chronic thyroiditis

Metastasis in two lymph nodes without capsular involvement among eleven lymph nodes (2/11).

Criteria	W 8/12/13	Yes	No

Source: NCI Genomic Data Commons file 9a07e9e9-f94c-4d91-9063-aa89f8a7c6c1 (TCGA-UF-A7JK.370E5296-CBC9-488F-BC5B-8C30656039CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).